Surgical pathology report (de-identified scan), TCGA case TCGA-NG-A4VW, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Roswell Park, specimen TCGA-NG-A4VW-01A (Primary Tumor).

[page 1 of 3]
ICD-6-3
Carcinosarcoma, mixed,
mullerian Tumor, malignant
8950/3

Site: Endometrium 254.1

gt 2/1/13

SPECIMENS:

- A. UTERUS, TUBES AND OVARIES
- B. LEFT PELVIC LYMPH NODE
- C. RIGHT PELVIC LYMPH NODE
- D. PERIAORTIC LYMPH NODE
- E. OMENTUM

DIAGNOSIS:

A. UTERUS, OVARIES AND FALLOPIAN TUBES, HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:

- MALIGNANT MIXED MULLERIAN TUMOR (MMMT) WITH HETEROLOGOUS CHONDROID ELEMENTS AND ENDOMETRIOID-TYPE EPITHELIAL COMPONENT.

- TUMOR INVADES >50% MYOMETRIAL THICKNESS (0.6/1.1 CM)
- CERVIX IS UNINVOLVED BY TUMOR
- FINAL SURGICAL MARGINS ARE FREE OF TUMOR
- SEE TEMPLATE
- SEE COMMENT.

- ADENOMYOSIS AND LEIOMYOMA.

- CERVIX WITH NO SIGNIFICANT PATHOLOGIC CHANGES.

- BILATERAL OVARIES AND FALLOPIAN TUBES NEGATIVE FOR MALIGNANCY.

B. LYMPH NODES, LEFT PELVIC, DISSECTION:

- SEVEN LYMPH NODES NEGATIVE FOR MALIGNANCY (0/7).

C. LYMPH NODES, RIGHT PELVIC, DISSECTION:

- FIFTEEN LYMPH NODES NEGATIVE FOR MALIGNANCY (0/15)

D. LYMPH NODES, PERIAORTIC, DISSECTION:

- FOUR LYMPH NODES NEGATIVE FOR MALIGNANCY (0/4).

E. OMENTUM, RESECTION:

- MATURE FIBROADIPOSE, NEGATIVE FOR MALIGNANCY.

SPECIMEN(S):

A. UTERUS, TUBES AND OVARIES B. LEFT PELVIC LYMPH NODE C. RIGHT PELVIC LYMPH NODE D. PERIAORTIC LYMPH NODE E. OMENTUM

CLINICAL HISTORY:

None given

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA. Uterus, tubes, and ovaries:

- Poorly differentiated endometrioid carcinoma invading about 30% of myometrial thickness in one section examined by Dr.

GROSS DESCRIPTION:

A. UTERUS, TUBES AND OVARIES:

Received fresh is a uterus with attached tubes and ovaries which weighs 109.5 grams and measures 8 x 5.5 x 4.5 cm. The ectocervix measures 3 x 3 cm with a white tan glistening mucosa. There is an anterior sub-serosal nodule that measures 2 x 2 x 1.5 cm. The remainder of the serosa is unremarkable. The uterus is opened laterally to reveal a maximal myometrial thickness of 1.5 cm. There is a tan-brown friable polypoid mass arising in the fundus which fills the entire endometrial cavity measuring, 4.6 x 3.2 x 3.0 cm. Sectioning through the myometrium reveals 30-40% invasion with focal areas suspicious for greater than 50% invasion grossly. The endometrial cavity measures 4 x 3.5 cm. Other than the large polypoid mass there are implants on the endometrial surface that range in size from 0.5 cm. in maximum dimension up to 1.5 cm. in maximum dimension. These are scattered over

[page 2 of 3]
the endometrial surface. The right ovary measures 2.7 x 1.2 x 1 cm and the right fallopian tube measures 8.6 x 0.3 cm in diameter. They are grossly unremarkable. The left ovary measures 2.5 x 1.5 x 1 cm and the left fallopian tube measures 7 x 0.4 cm in diameter. They are also grossly unremarkable. The parametrium is inked in black. Representative sections are submitted as follows:

- A1: frozen section to show myometrial invasion
- A2: anterior cervix
- A3: posterior cervix
- A4: anterior lower uterine segment
- A5: posterior lower uterine segment
- A6: anterior fundal area with tumor to demonstrate invasion
- A7-A8: anterior endomyometrium with subserosal nodule
- A9: posterior endomyometrium
- A10-A11: endometrium demonstrating surface implants
- A12: representative section of tumor
- A13: representative sections of right fallopian tube
- A14: representative sections of right ovary
- A15: representative sections of left fallopian tube
- A16: representative sections of left ovary
- A17: right parametrium
- A18: left parametrium

B. LEFT PELVIC LYMPH NODES:

Received in formalin are multiple fragments of fibroadipose tissue measuring 6.3 x 4.5 x 1.5 cm. Seven possible lymph nodes are identified, the largest measures 4.5 x 2.3 x 0.5 cm. This large node is cut in half and then bisected and submitted in toto in B1-B4. Representative sections are submitted as follows:

- B1-B4: largest lymph node cut in half and bisected, submitted in toto
- B5-B6: lymph node bisected and submitted in toto
- B7: lymph node bisected and submitted in toto
- B8: lymph node bisected and submitted in toto
- B9: one possible lymph node
- B10: two possible lymph nodes

C. RIGHT PELVIC LYMPH NODES:

Received in formalin are multiple fragments of fibroadipose tissue measuring 6.5 x 3 x 0.9 cm. in aggregate. Nine possible lymph nodes are identified ranging in size from 2.5 x 1.5 x 0.5 to 0.9 x 0.6 x 0.5 cm. These are submitted in toto as follows:

- C1-C2: large lymph node bisected
- C3: lymph node bisected and submitted in toto
- C4: lymph node bisected and submitted in toto
- C5: two possible lymph nodes
- C6: one lymph node bisected and submitted in toto
- C7: one lymph node bisected and submitted in toto
- C8: one lymph node bisected and submitted in toto
- C9: one lymph node bisected and submitted in toto

D. PERIAORTIC LYMPH NODES

Received in formalin are four fragments of fibroadipose tissue ranging in size from 0.7 x 0.4 x 0.3 up to 2 x 1.5 x 1 cm. Four possible lymph nodes are identified. These are submitted in toto as follows:

- D1: one possible lymph node
- D2: one lymph node bisected and submitted in toto
- D3: two possible lymph nodes submitted in toto

E. OMENTUM:

Received in formalin is a segment of fibroadipose tissue measuring 23 x 7.5 x 2.5 cm. There are no obvious nodules or tumor implants on the surface. The specimen is carefully sectioned to reveal no lesions or masses. Representative sections are submitted in E1-E3 for microscopic examination.

COMMENT:

This predominately polypoid tumor is composed of a glandular component taking the form of endometrioid carcinoma, which is intimately admixed with a mesenchymal component in many areas. The malignant mesenchymal element has a myxoid and occasionally chondroid appearance. It is positive for vimentin and negative for CK AE 1/3. A few small foci of tumor show staining for synaptophysin and chromogranin A. Portions of this case were reviewed at departmental conference on and there was agreement with assessment.

[page 3 of 3]
ENDOMETRIAL CANCER TEMPLATE

Prior Biopsy Specimen:	
Prior Biopsy Diagnosis:	Adenocarcinoma with spindle cell component
Specimen Type:	Hysterectomy
Tumor Size:	4.6 x 3.2 x 3.0 cm
Histological Type:	MMMT (Carcinosarcoma)
Histological Grade:	Endometrioid component is FIGO II
Extent of Invasion:	Myometrium (6/11 MM)
Cervical Invasion:	Absent
Margins:	Uninvolved
Distance to Closest Margin:	Not applicable
Angiolymphatic Invasion:	Absent
Additional Findings:	None
Lymph Nodes:	Negative
Right Pelvic:	Negative (0/15)
Left Pelvic:	Negative (0/7)
Para-aortic:	Negative (0/4)
Other Tissue Removed:	Omentum
Other Positive Sites:	None
Peritoneal Cytology:	Negative
Pathological Stage:	pT1c N0 Mx

Criteria	lw 11/30/13	Yes	No
Dual/Synchronous Primacy Noted			✓

Source: NCI Genomic Data Commons file 71358b23-b88e-4149-8afb-a65ba4c7d846 (TCGA-NG-A4VW.0E53A074-3A7D-4C4B-8336-9C53DA3AF315.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).